Somatic mutation profile of tumor specimen TCGA-EE-A3J3-06A (aliquot TCGA-EE-A3J3-06A-11D-A20D-08) from TCGA case TCGA-EE-A3J3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Amelanotic melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.4 years (20,585 days).
Specimen TCGA-EE-A3J3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b31f070a-0771-4372-8627-e9f2e1d76a14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3J3-10A (Blood Derived Normal), aliquot TCGA-EE-A3J3-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc60f683-19ac-48c3-9ab5-ba24ac7d89dd

The open-access MAF lists 208 somatic variants for this specimen: 127 protein-altering or splice-affecting, 76 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 76, Nonsense Mutation 12, RNA 2, Splice Region 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB6 | c.419T>G p.I140S | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.015); catalogued as COSV54697755; called by muse, mutect2, varscan2
- ACTRT2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV65759776; called by muse, mutect2, varscan2
- ADGRB1 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs368988728; called by muse, mutect2, varscan2
- AKAP10 | c.255T>G p.S85R | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV56732037; called by muse, mutect2, varscan2
- AL358113.1 | c.3944G>A p.R1315Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.973); catalogued as rs201144827, COSV61957413; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPI | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55015254; called by muse, mutect2, varscan2
- APAF1 | c.1917A>T p.L639F (on ENST00000551964 / NM_181861.2; = p.L628F on NM_001160.3) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs765006856, COSV59665742; called by muse, mutect2, varscan2
- ATXN2L | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs779760189, COSV57369460; called by muse, mutect2, varscan2
- AXIN2 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV61058718; called by muse, mutect2, varscan2
- BICC1 | c.490T>A p.C164S | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV65862191; called by muse, mutect2, varscan2
- BPIFB3 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs747168207, COSV64957637, COSV64958364; called by muse, mutect2, varscan2
- BRINP3 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV100818685, COSV66530646; called by muse, mutect2, varscan2
- BRPF1 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 42/55 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57406225; called by muse, mutect2, varscan2
- C1QTNF9 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752786322, COSV59656811; called by muse, mutect2, varscan2
- C3 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 83/275 reads (30%) | catalogued as CM113003, COSV55576104; called by muse, mutect2, varscan2
- C8orf34 | c.1326C>T p.F442= | Splice Region (SNP) | VAF 6/27 reads (22%) | catalogued as rs201463505, COSV57396967; called by muse, mutect2, varscan2
- CAPN1 | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as COSV54198728; called by muse, mutect2, varscan2
- CAPN9 | c.1899G>T p.Q633H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55236308; called by muse, mutect2, varscan2
- CBL | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99876488; called by muse, mutect2, varscan2
- CBL | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50631432; called by muse, mutect2, varscan2
- CDC14A | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV60560216; called by muse, mutect2, varscan2
- CEP135 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1279411788, COSV57261342; called by muse, mutect2, varscan2
- CHI3L1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV55137170; called by muse, mutect2, varscan2
- CHRNA6 | c.1096G>A p.G366S | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.65); PolyPhen benign (0.009); catalogued as COSV52380262; called by muse, mutect2, varscan2
- CILP | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.607); catalogued as rs371987972; called by muse, mutect2, varscan2
- CLPTM1L | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.336); catalogued as COSV57991413; called by muse, mutect2, varscan2
- COL21A1 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769722166, COSV55163893, COSV99778638; called by muse, mutect2, varscan2
- COL4A2 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161540, COSV64624792, COSV64630594; called by muse, mutect2, varscan2
- CSAG1 | c.188G>A p.R63K | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV63400109, COSV63400725; called by muse, mutect2, varscan2
- CSMD1 | c.3130G>A p.E1044K (on ENST00000520002; = p.E1043K on NM_033225.6) | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV59346983; called by muse, mutect2, varscan2
- CYP20A1 | c.584A>G p.Q195R | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61909879; called by muse, mutect2, varscan2
- DCSTAMP | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV52578773; called by muse, mutect2, varscan2
- DNHD1 | c.12143G>A p.R4048Q | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as rs2288284, COSV54439181; called by muse, varscan2
- DSCAM | c.2203C>T p.Q735* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1413162428, COSV68030912; called by muse, mutect2, varscan2
- DYSF | c.2402A>G p.D801G | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.5); catalogued as rs1434152276, COSV50469213; called by muse, mutect2, varscan2
- EML1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV51748318; called by muse, mutect2, varscan2
- EPHB2 | c.1843G>A p.E615K (on ENST00000400191 / NM_001309193.2; = p.E616K on NM_004442.7) | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV65863907; called by muse, mutect2, varscan2
- FAM83H | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV66354147; called by muse, mutect2, varscan2
- GGA2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100564742; called by muse, mutect2, varscan2
- GLI1 | c.3292G>C p.E1098Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57364340, COSV57364569, COSV57368767; called by muse, mutect2, varscan2
- GLI2 | c.1732G>A p.V578I (on ENST00000361492 / NM_001374353.1; = p.V595I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as rs768557650, COSV58043749; called by muse, mutect2, varscan2
- GLI2 | c.4403C>T p.P1468L (on ENST00000361492 / NM_001374353.1; = p.P1485L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV58045898, COSV58047663; called by muse, mutect2, varscan2
- GLUL | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV59382717; called by muse, mutect2, varscan2
- GPR142 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs367783578; called by muse, mutect2, varscan2
- GPR50 | c.1375C>T p.H459Y | Missense Mutation (SNP) | VAF 269/349 reads (77%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV54439190; called by muse, mutect2, varscan2
- GPR65 | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 44/97 reads (45%) | catalogued as COSV50863324; called by muse, mutect2, varscan2
- HDC | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51069929; called by muse, mutect2, varscan2
- HIVEP1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs1483954407, COSV65103228; called by muse, mutect2
- HRNR | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs372592483; called by muse, mutect2, varscan2
- HS3ST5 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57145255; called by muse, mutect2, varscan2
- ILDR1 | c.1211G>A p.R404H (on ENST00000344209 / NM_001199799.2; = p.R360H on NM_175924.4) | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs150479416; called by muse, mutect2, varscan2
- ITGA5 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.216); catalogued as COSV53219224; called by muse, mutect2, varscan2
- ITGAE | c.3500C>T p.A1167V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV53996592; called by muse, mutect2, varscan2
- KCNH4 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.236); catalogued as COSV52919117; called by muse, mutect2, varscan2
- KCNH7 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV59794581; called by muse, mutect2, varscan2
- KCTD8 | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 34/350 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.17); catalogued as COSV63589513, COSV63591967; called by muse, mutect2
- KIF5A | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978901860, COSV54051656, COSV54056748; called by muse, mutect2, varscan2
- KLHL20 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV52943382; called by muse, mutect2, varscan2
- KRIT1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV60669135; called by muse, mutect2, varscan2
- LRP4 | c.4273C>T p.R1425* | Nonsense Mutation (SNP) | VAF 106/153 reads (69%) | catalogued as rs1247207663, COSV66135827; called by muse, mutect2, varscan2
- MARCO | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV59052236; called by muse, mutect2, varscan2
- MDM4 | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs1401673629, COSV65794954, COSV65796191; called by muse, mutect2, varscan2
- MED12L | c.5273G>A p.G1758E | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.235); catalogued as COSV56386003; called by muse, mutect2, varscan2
- MMP24 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.172); catalogued as rs781019666, COSV55771384, COSV55773115; called by muse, mutect2, varscan2
- MSRA | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57805848; called by muse, mutect2, varscan2
- MUC16 | c.25976C>T p.S8659F | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.029); catalogued as rs768830849, COSV67478111; called by muse, mutect2, varscan2
- MYH10 | c.2824C>T p.Q942* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV52605109; called by muse, mutect2, varscan2
- MYH4 | c.1587G>T p.K529N | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV55121906; called by mutect2, varscan2
- NFATC3 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60476038; called by muse, mutect2, varscan2
- NPM1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV51566369; called by muse, mutect2, varscan2
- NSUN5 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs531435819, COSV53091873, COSV99392251; called by muse, mutect2, varscan2
- OR1K1 | c.277A>C p.I93L | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52956807; called by muse, mutect2, varscan2
- OR2T5 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.033); catalogued as rs1329949330, COSV100822179, COSV100822212; called by mutect2, varscan2
- OR52D1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV59487884; called by muse, mutect2, varscan2
- OR6K6 | c.575C>T p.S192F (on ENST00000368144; = p.S168F on NM_001005184.1) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.926); catalogued as COSV63744422; called by muse, mutect2, varscan2
- PAMR1 | c.2029G>A p.A677T (on ENST00000619888 / NM_001001991.3; = p.A694T on NM_015430.4) | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV53514070; called by muse, mutect2, varscan2
- PARP6 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 39/56 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV53003949, COSV99536297; called by muse, mutect2, varscan2
- PCDH15 | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 81/116 reads (70%) | catalogued as rs762029000, COSV57273789; called by muse, mutect2, varscan2
- PCDHA4 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV63543526; called by muse, mutect2, varscan2
- PGK2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 92/114 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59163049; called by muse, mutect2, varscan2
- PGLYRP1 | c.365G>A p.W122* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV50517062; called by muse, mutect2, varscan2
- PIGM | c.1195A>C p.I399L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.472); catalogued as COSV63635808, COSV63635985; called by muse, mutect2, varscan2
- PKHD1L1 | c.10077C>A p.D3359E | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.053); catalogued as COSV65747142; called by muse, mutect2, varscan2
- PLA2G4C | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV62786340; called by muse, mutect2, varscan2
- PLCXD2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 41/59 reads (69%) | catalogued as rs571921225, COSV67341126; called by muse, mutect2, varscan2
- POTEE | c.620G>A p.R207K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); catalogued as COSV100388584; called by mutect2, varscan2
- RAD51AP2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.088); catalogued as COSV67588520; called by muse, mutect2, varscan2
- RB1CC1 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 31/55 reads (56%) | catalogued as COSV50256555; called by muse, mutect2, varscan2
- ROR2 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV65221104; called by muse, mutect2, varscan2
- RYR1 | c.1142G>A p.G381D | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62102845; called by muse, mutect2, varscan2
- SELENBP1 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs1287391825, COSV64373759; called by muse, mutect2, varscan2
- SEMA6B | c.1119C>T p.P373= | Splice Region (SNP) | VAF 29/74 reads (39%) | catalogued as COSV56704899; called by muse, mutect2, varscan2
- SIX4 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV53669774; called by muse, mutect2, varscan2
- SLC24A1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV56052776; called by muse, mutect2, varscan2
- SLC5A4 | c.206C>G p.P69R | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs763808657, COSV56671891; called by muse, mutect2, varscan2
- SLURP1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs139944345; called by muse, mutect2, varscan2
- SPAG16 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59105945; called by muse, mutect2
- SPP1 | c.475C>T p.R159* (on ENST00000395080 / NM_001040058.2; = p.R145* on NM_000582.2) | Nonsense Mutation (SNP) | VAF 43/105 reads (41%) | catalogued as rs1269833822, COSV52952154, COSV99420931; called by muse, mutect2, varscan2
- TCL1B | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.067); catalogued as rs1295758166, COSV100525795; called by muse, mutect2, varscan2
- TEP1 | c.4862C>T p.P1621L | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766303079, COSV52995701; called by muse, mutect2, varscan2
- THADA | c.5083C>T p.P1695S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs773079245, COSV57687684; called by muse, mutect2, varscan2
- THSD7B | c.2452G>A p.G818R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV55669450; called by muse, mutect2, varscan2
- TJP1 | c.4403C>T p.S1468F | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.429); catalogued as COSV62043617; called by muse, mutect2, varscan2
- TNR | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54898003; called by muse, mutect2, varscan2
- TNR | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs769270385, COSV54876723, COSV54877373, COSV99690820; called by muse, mutect2, varscan2
- TNXB | c.6290G>A p.G2097D (on ENST00000647633; = p.G1850D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/95 reads (84%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as COSV64482940; called by muse, mutect2, varscan2
- TP53BP2 | c.1479T>G p.D493E (on ENST00000343537 / NM_001031685.3; = p.D364E on NM_005426.2) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV59070312; called by muse, mutect2, varscan2
- TRIM23 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV51552758; called by muse, mutect2, varscan2
- TSGA13 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV58405904; called by muse, mutect2, varscan2
- UGT2B28 | c.158T>G p.V53G | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59433097; called by muse, mutect2, varscan2
- UNC13C | c.1742C>T p.S581F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV52895571; called by muse, mutect2, varscan2
- VENTX | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs771301636, COSV58084940; called by muse, mutect2, varscan2
- VSIG10 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV63653889; called by muse, mutect2, varscan2
- WFDC8 | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.042); catalogued as COSV51490486, COSV51492075; called by muse, mutect2, varscan2
- WNT10A | c.315G>A p.W105* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV51463076; called by muse, mutect2, varscan2
- WNT9A | c.727C>G p.L243V | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55295752; called by muse, mutect2, varscan2
- WSCD1 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as rs748124029, COSV58496578; called by muse, mutect2, varscan2
- ZAN | c.2464C>T p.P822S | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as rs768024017, COSV61811556, COSV61813248; called by muse, mutect2, varscan2
- ZFHX3 | c.8198G>A p.R2733H | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1277890729, COSV51725279, COSV51734057; called by muse, mutect2, varscan2
- ZFYVE21 | c.379T>C p.F127L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52453643; called by muse, mutect2, varscan2
- ZMYND8 | c.2239C>T p.P747S (on ENST00000311275 / NM_001363741.2; = p.P767S on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV53686422; called by muse, mutect2, varscan2
- ZNF583 | c.1544C>T p.T515I | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV52403424; called by muse, mutect2, varscan2
- ZNF616 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.035); catalogued as COSV57512051; called by muse, mutect2, varscan2
- CFAP52 | c.1541dup p.F515Vfs*19 | Frame Shift Ins (INS) | VAF 14/96 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.1688T>A p.F563Y | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SSU72P8 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABI3 | c.255G>A p.Q85= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV56800740; called by muse, mutect2, varscan2
- ABI3 | c.537C>T p.S179= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56800753; called by muse, mutect2
- ADAM12 | c.1698G>A p.S566= | Silent (SNP) | VAF 52/87 reads (60%) | catalogued as rs781611901, COSV64109877; called by muse, mutect2, varscan2
- ADCY5 | c.2448C>T p.F816= | Silent (SNP) | VAF 33/46 reads (72%) | catalogued as COSV59200532; called by muse, mutect2, varscan2
- AFF3 | c.375C>T p.I125= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV57860985; called by muse, mutect2, varscan2
- AGPAT4 | c.1029C>T p.L343= | Silent (SNP) | VAF 72/124 reads (58%) | catalogued as rs374473460; called by muse, mutect2, varscan2
- ALB | c.477G>A p.L159= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55739888; called by muse, mutect2, varscan2
- BDP1 | c.2814C>T p.S938= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV62432591; called by muse, mutect2, varscan2
- CATSPERG | c.2760C>T p.L920= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs759558117, COSV53050584; called by muse, mutect2, varscan2
- CCKAR | c.1065C>T p.I355= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV55162464; called by muse, mutect2, varscan2
- CFAP251 | c.3214C>T p.L1072= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV56612447; called by muse, mutect2, varscan2
- CFHR4 | c.1308C>T p.S436= (on ENST00000367416 / NM_001201551.2; = p.S190= on NM_006684.5) | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV52231709, COSV99259590; called by muse, mutect2, varscan2
- CHTF18 | c.2481C>T p.F827= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs751926698, COSV50210710; called by muse, mutect2, varscan2
- CLASP2 | c.3810T>G p.P1270= (on ENST00000359576; = p.P1269= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV56286855; called by muse, varscan2
- CMYA5 | c.1362C>T p.D454= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as COSV71407377; called by muse, mutect2, varscan2
- COL2A1 | c.3870C>T p.H1290= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs139957398; called by muse, mutect2, varscan2
- DCLRE1B | c.1260G>A p.K420= | Silent (SNP) | VAF 43/196 reads (22%) | catalogued as COSV65813173; called by muse, mutect2, varscan2
- DEPDC7 | c.1044G>A p.K348= (on ENST00000241051 / NM_001077242.2; = p.K339= on NM_139160.2) | Silent (SNP) | VAF 51/64 reads (80%) | catalogued as COSV53808020; called by muse, mutect2, varscan2
- DHTKD1 | c.2088C>T p.L696= | Silent (SNP) | VAF 46/71 reads (65%) | catalogued as rs1255684246, COSV53804859; called by muse, mutect2, varscan2
- DNAH7 | c.10611G>A p.V3537= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV56765441; called by muse, mutect2, varscan2
- DNAH8 | c.10653C>A p.I3551= | Silent (SNP) | VAF 91/209 reads (44%) | catalogued as COSV59427927, COSV59461879, COSV59468585; called by muse, mutect2, varscan2
- DTNBP1 | c.561C>G p.T187= | Silent (SNP) | VAF 26/254 reads (10%) | catalogued as COSV59041860; called by muse, mutect2, varscan2
- EGFLAM | c.588C>T p.I196= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV59308814; called by muse, mutect2, varscan2
- ELANE | c.726C>T p.I242= | Silent (SNP) | VAF 100/282 reads (35%) | catalogued as COSV55048520; called by muse, mutect2, varscan2
- ENTPD3 | c.204C>T p.T68= | Silent (SNP) | VAF 116/147 reads (79%) | catalogued as COSV57195312; called by muse, mutect2, varscan2
- FAM83E | c.1119C>T p.S373= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV52377196; called by muse, mutect2, varscan2
- FCRL3 | c.1515G>A p.P505= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs138291587; called by muse, mutect2, varscan2
- GBP2 | c.702C>T p.F234= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs773133578, COSV65069852; called by muse, mutect2, varscan2
- GGA2 | c.687C>T p.S229= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV100564739; called by muse, mutect2, varscan2
- GPR142 | c.1164G>A p.R388= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs1296767530, COSV59519406; called by muse, mutect2, varscan2
- GRID1 | c.1494C>T p.N498= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV60038825; called by muse, mutect2, varscan2
- HMMR | c.1557A>G p.S519= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV62374940; called by muse, mutect2, varscan2
- HTR2C | c.615G>A p.T205= | Silent (SNP) | VAF 86/108 reads (80%) | catalogued as rs1556486803, COSV52217696; called by muse, mutect2, varscan2
- KBTBD13 | c.108C>T p.F36= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV71351628; called by muse, mutect2
- KLHDC10 | c.918C>T p.P306= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV59052686; called by muse, mutect2, varscan2
- KLHL1 | c.1266T>C p.N422= | Silent (SNP) | VAF 73/200 reads (37%) | catalogued as COSV100917041, COSV64776014; called by muse, mutect2, varscan2
- MAB21L2 | c.915G>T p.L305= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV58262608; called by muse, mutect2, varscan2
- MAST3 | c.126C>T p.L42= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as COSV53223092; called by muse, mutect2, varscan2
- MCPH1 | c.1672C>T p.L558= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs545753077, COSV60915944; called by muse, mutect2, varscan2
- MMP27 | c.1353G>A p.K451= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as COSV52781672, COSV99498780; called by muse, mutect2, varscan2
- MYH2 | c.5442G>A p.G1814= | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV55442271; called by muse, mutect2, varscan2
- MYH6 | c.1863C>T p.L621= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs201043980, COSV62452398; called by muse, mutect2, varscan2
- MYO1B | c.1623C>T p.A541= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV58433958; called by muse, mutect2, varscan2
- NBPF11 | c.1671C>T p.P557= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as rs1302595060; called by muse, mutect2, varscan2
- NLRP8 | c.1146C>T p.F382= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as rs371309780; called by muse, mutect2, varscan2
- NPTN | c.330C>T p.D110= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV54738350; called by muse, mutect2, varscan2
- NUP62CL | c.438A>G p.E146= | Silent (SNP) | VAF 64/80 reads (80%) | catalogued as COSV65236367; called by muse, mutect2, varscan2
- NXPH2 | c.591G>A p.A197= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs754687148, COSV55643018; called by mutect2, varscan2
- OR2L3 | c.873G>A p.L291= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV63455335, COSV63455752; called by muse, mutect2, varscan2
- OR6S1 | c.588G>A p.K196= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs1326874961, COSV57838671; called by muse, mutect2, varscan2
- OR8A1 | c.348A>C p.T116= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV52509167; called by muse, mutect2, varscan2
- PCDHA7 | c.2049G>A p.S683= | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as rs1562358225, COSV100970984, COSV65336822; called by muse, mutect2, varscan2
- PCDHB15 | c.567G>A p.R189= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as rs1039707853, COSV51049411; called by muse, mutect2, varscan2
- PDS5B | c.2793C>T p.S931= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs532052707, COSV59730028; called by muse, mutect2, varscan2
- PGP | c.636C>T p.I212= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs1275587267, COSV57029627; called by muse, mutect2, varscan2
- PLA2G4C | c.963C>T p.S321= | Silent (SNP) | VAF 73/219 reads (33%) | catalogued as rs1272497747, COSV100843960; called by muse, mutect2, varscan2
- PTH2R | c.343T>C p.L115= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV55917750; called by muse, mutect2, varscan2
- RERGL | c.519G>A p.L173= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV57462363; called by muse, mutect2, varscan2
- ROR2 | c.1746G>A p.T582= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs201241207, COSV100995612, COSV100995881; called by muse, mutect2, varscan2
- SALL4 | c.2871C>T p.I957= | Silent (SNP) | VAF 52/128 reads (41%) | catalogued as rs763706687, COSV53854051; called by muse, mutect2, varscan2
- SEMG2 | c.1125G>A p.S375= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs747025306, COSV65647142; called by muse, mutect2, varscan2
- SH2B2 | c.939G>A p.K313= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV60826834; called by muse, mutect2, varscan2
- SIM1 | c.1269C>T p.A423= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as rs753644529, COSV53494098; called by muse, mutect2, varscan2
- SLC4A11 | c.723G>T p.G241= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV66262744; called by muse, mutect2, varscan2
- SPTA1 | c.5610C>T p.V1870= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as rs369902263, COSV63756299; called by muse, mutect2, varscan2
- ST14 | c.570C>T p.S190= | Silent (SNP) | VAF 50/89 reads (56%) | catalogued as COSV53834640; called by muse, mutect2, varscan2
- TAS2R43 | c.273C>T p.I91= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV67858460; called by muse, mutect2, varscan2
- TCL1B | c.36C>T p.P12= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as rs773337089, COSV100525797; called by muse, mutect2, varscan2
- TENM2 | c.4014C>G p.P1338= (on ENST00000518659 / NM_001122679.2; = p.P1099= on NM_001080428.3) | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as COSV101317746, COSV101319487, COSV69135332; called by muse, mutect2, varscan2
- TMEM63B | c.849C>T p.F283= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV52480646; called by muse, mutect2, varscan2
- VANGL2 | c.157C>T p.L53= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV63604883; called by muse, mutect2
- VPS13D | c.11670C>T p.F3890= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV50653436; called by muse, mutect2, varscan2
- XIRP2 | c.4929G>A p.K1643= (on ENST00000628543; = p.K1818= on NM_152381.6) | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV54714468; called by muse, mutect2, varscan2
- XPO1 | c.1740C>G p.V580= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV68946690; called by muse, mutect2, varscan2
- ZFYVE28 | c.144G>A p.R48= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs185700553, COSV52113889; called by muse, mutect2, varscan2
- ZNF44 | c.1029C>T p.S343= (on ENST00000356109 / NM_001164276.2; = p.S295= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV61135791; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848004 G>A | 5'Flank (SNP) | VAF 28/35 reads (80%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851045 G>A | 3'Flank (SNP) | VAF 53/68 reads (78%) | catalogued as rs1367775985; called by muse, mutect2, varscan2
- PCDHB7 | c.-2G>A | 5'UTR (SNP) | VAF 24/66 reads (36%) | catalogued as COSV99177078, COSV99177506; called by muse, mutect2, varscan2
- TUBB7P | n.235G>A | RNA (SNP) | VAF 66/161 reads (41%) | called by muse, mutect2, varscan2
- TUBB7P | n.234G>A | RNA (SNP) | VAF 68/162 reads (42%) | called by muse, mutect2, varscan2
